Somatic mutation profile of tumor specimen TCGA-B8-5159-01A (aliquot TCGA-B8-5159-01A-01D-1421-08) from TCGA case TCGA-B8-5159, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.5 years (22,462 days).
Specimen TCGA-B8-5159-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93c6240e-94fa-4805-bb7b-b51d32ce40c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5159-10A (Blood Derived Normal), aliquot TCGA-B8-5159-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86d4e39b-ad96-4f15-8e00-2026af5f35ee

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, In Frame Del 1, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.529A>T p.R177* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as rs1559429717, CM961438, COSV56552627, COSV56563258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.14236G>C p.E4746Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV67986156, COSV67996755; called by muse, mutect2, varscan2
- AR | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65956711; called by muse, mutect2, varscan2
- CAMKK2 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV61218281; called by muse, mutect2, varscan2
- CATSPER3 | c.720A>C p.E240D | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50951068; called by muse, mutect2, varscan2
- CCDC125 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 47/191 reads (25%) | catalogued as COSV67289039; called by muse, mutect2, varscan2
- CEP41 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56221541; called by muse, mutect2, varscan2
- CMTM4 | c.274T>C p.C92R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58064055; called by muse, mutect2, varscan2
- CNOT1 | c.6955C>T p.P2319S | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54701705; called by muse, mutect2, varscan2
- CTNND2 | c.3247C>A p.L1083I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.952); catalogued as COSV58934159; called by muse, mutect2, varscan2
- CZIB | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53760605; called by muse, mutect2, varscan2
- DCAF11 | c.780G>C p.R260S | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV58110986; called by muse, mutect2, varscan2
- DHCR7 | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as CD051731, COSV62796922; called by muse, mutect2, varscan2
- ELF1 | c.360A>T p.I120= | Splice Region (SNP) | VAF 38/83 reads (46%) | catalogued as rs1221470578, COSV53503445; called by muse, mutect2, varscan2
- ETFDH | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.232); catalogued as COSV56989402; called by muse, mutect2, varscan2
- GABRA5 | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV59486695; called by muse, mutect2, varscan2
- JADE2 | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.184); catalogued as COSV50936429, COSV50938575; called by muse, mutect2, varscan2
- KRT36 | c.939A>T p.R313S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60204929; called by muse, mutect2, varscan2
- LAMA4 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54571477, COSV99038962; called by muse, mutect2, varscan2
- MARF1 | c.1503dup p.R502Qfs*17 | Frame Shift Ins (INS) | VAF 29/105 reads (28%) | catalogued as rs1490902246; called by mutect2, pindel, varscan2
- MICAL2 | c.4588T>A p.S1530T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56289182; called by muse, mutect2, varscan2
- MRGPRX4 | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV58591943; called by muse, mutect2, varscan2
- MRPS15 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV64152795; called by muse, mutect2, varscan2
- NEDD1 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV57147228; called by muse, mutect2, varscan2
- NPHS1 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs758994022, COSV62290210; called by muse, mutect2, varscan2
- PIK3CA | c.816T>A p.Y272* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV56012610; called by muse, mutect2, varscan2
- RP1 | c.134A>C p.D45A | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55128677; called by muse, mutect2, varscan2
- SLC22A5 | c.67_69del p.F23del | In Frame Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs377767444; called by pindel, varscan2
- SMC3 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62421855; called by muse, mutect2, varscan2
- THEM5 | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.866); catalogued as COSV64312814, COSV64313313; called by muse, mutect2, varscan2
- TRIM71 | c.1375G>C p.V459L | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV67472911; called by muse, mutect2, varscan2
- WDR72 | c.1805T>A p.I602N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.365); catalogued as COSV64754783; called by muse, mutect2, varscan2
- ZBTB5 | c.1082T>G p.V361G | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV57042077; called by muse, mutect2, varscan2
- ZCCHC8 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60320458; called by muse, mutect2
- ZDBF2 | c.5214A>T p.E1738D | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV65630721; called by muse, mutect2, varscan2
- ZFAT | c.3297A>C p.E1099D | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.352); catalogued as COSV64748633; called by muse, mutect2, varscan2
- ZNF185 | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV59278479; called by muse, mutect2
- ZNF281 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54170219; called by muse, mutect2
- ZNF638 | c.5737T>C p.S1913P | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52498402; called by muse, mutect2, varscan2
- ZSWIM8 | c.2521T>G p.L841V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV67135280; called by muse, mutect2, varscan2
- LRRC37A | c.2761T>A p.S921T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- MYH7B | c.1691_1700del p.C564Sfs*80 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- NGLY1 | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TYR | c.29_30insA p.W11Vfs*12 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- YLPM1 | c.359del p.Q120Rfs*99 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ZNF592 | c.568_572del p.P190Sfs*7 | Frame Shift Del (DEL) | VAF 48/161 reads (30%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.2535C>T p.V845= (on ENST00000506720 / NM_001322402.2; = p.V777= on NM_015236.6) | Silent (SNP) | VAF 83/265 reads (31%) | catalogued as rs761628517, COSV72229529, COSV72232153; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1077C>A p.I359= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV52272550; called by muse, mutect2, varscan2
- KARS1 | c.9C>A p.A3= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, varscan2
- MAPK7 | c.783C>G p.L261= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV55192172; called by muse, mutect2, varscan2
- PAPPA2 | c.4353G>C p.G1451= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV62813999; called by muse, mutect2, varscan2
- PATJ | c.2649A>G p.S883= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV57173396; called by muse, mutect2, varscan2
- PPFIBP1 | c.2145T>C p.N715= (on ENST00000318304 / NM_177444.3; = p.N709= on NM_003622.4) | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as COSV57299737; called by muse, mutect2, varscan2
- TMEM132B | c.1644C>T p.S548= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs767749096, COSV54773325; called by muse, mutect2, varscan2
- UBP1 | c.6C>A p.A2= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV52148093; called by mutect2, varscan2
- ILF3 | c.*1G>C | 3'UTR (SNP) | VAF 34/114 reads (30%) | catalogued as COSV99140415; called by muse, mutect2, varscan2
- NACA | c.71-1626C>T | Intron (SNP) | VAF 94/230 reads (41%) | catalogued as rs1242643990, COSV63273594; called by muse, mutect2, varscan2
- PDXK | c.88-1625T>G | Intron (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99376769; called by muse, mutect2, varscan2
- PHF6 | c.-2T>C | 5'UTR (SNP) | VAF 118/222 reads (53%) | catalogued as COSV100136935; called by muse, mutect2, varscan2
